TCGA case TCGA-F4-6460 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2a7bbafe-d499-4241-ba3d-a52ba0a5db3c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 51 years; Vital status: Dead; Days to death: 972 days (2.7 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 51.0 years (18,637 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 972 days (2.7 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 6; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 229 days; Number of cycles: 10; Treatment dose: 640 g/day; Prescribed dose: 4; Prescribed dose units: g/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 138 days; Number of cycles: 6; Treatment dose: 900 mg; Prescribed dose: 150; Prescribed dose units: mg/day; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Raltitrexed; Treatment intent type: Adjuvant; Days to treatment start: 313 days; Number of cycles: 5; Treatment outcome: Treatment Ongoing; Prescribed dose: 4; Prescribed dose units: g/day; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Liver; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 51.9 years (18,950 days); Days to diagnosis: 313 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Day 313 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to recurrence: 313 days.
- Days to follow up: 407 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 972 days (2.7 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 73 kg; Height: 168 cm; BMI: 25.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F4-6460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-F4-6460-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide TCGA-F4-6460-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 71; Percent normal cells: 14; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
- Sample TCGA-F4-6460-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F4-6460-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 972 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 972 days; disease-free interval: event (new tumor event after initially disease-free), 313 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 313 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F4-6460-01A-11D-1770-01): tumor purity 0.6, ploidy 2.82, whole-genome doublings 1.
